MMRF case MMRF_1645 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/eb6fa8f1-a587-4883-9e84-8d699360f563

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 36 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 36.1 years (13,200 days); ISS stage: III; Days to last known disease status: 1,156 days (3.2 years); Days to last follow up: 1,156 days (3.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 117 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 180 days; Days to treatment end: 370 days (1.0 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 180 days; Days to treatment end: 439 days (1.2 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 440 days (1.2 years); Days to treatment end: 440 days (1.2 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 440 days (1.2 years); Days to treatment end: 440 days (1.2 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 540 days (1.5 years); Days to treatment end: 943 days (2.6 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 943 days (2.6 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 2390 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.98 mg/dL; Immunoglobulin G 2.61 g/L; Immunoglobulin A 73 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 5.96 µg/mL; Lactate Dehydrogenase 5.05 µkat/L; Hemoglobin 4.71 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 1990 µmol/L; Blood Urea Nitrogen 32.5 mmol/L; Calcium 2.4 mmol/L; Albumin 35 g/L; Total Protein 6.7 g/dL; Glucose 4.73 mmol/L; C-Reactive Protein 4.22 mg/dL.
- Day 98 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 300 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 4.16 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 4.08 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 478 µmol/L; Blood Urea Nitrogen 15.7 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 5.72 mmol/L.
- Day 175 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 148 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 4.59 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.21 g/L; Lactate Dehydrogenase 4.47 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 242 ×10⁹/L; Creatinine 523 µmol/L; Blood Urea Nitrogen 19.6 mmol/L; Calcium 2.5 mmol/L; Albumin 48 g/L; Total Protein 7.9 g/dL; Glucose 6.33 mmol/L.
- Day 293: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 23.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.71 mg/dL; Immunoglobulin G 2.96 g/L; Immunoglobulin A 0.54 g/L; Immunoglobulin M 0 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 13.8 ×10⁹/L; Absolute Neutrophil 10.6 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 399 µmol/L; Blood Urea Nitrogen 17.9 mmol/L; Calcium 1.95 mmol/L; Albumin 33 g/L; Total Protein 5.6 g/dL; Glucose 8.09 mmol/L.
- Day 370: Serum Free Immunoglobulin Light Chain, Kappa 65.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 7.91 g/L; Immunoglobulin A 0.9 g/L; Immunoglobulin M 0.38 g/L; Hemoglobin 7.63 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 333 ×10⁹/L; Creatinine 388 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 7.4 g/dL; Glucose 5.61 mmol/L.
- Day 467: Hemoglobin 6.7 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 3.87 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 408 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 32 g/L; Total Protein 6.4 g/dL; Glucose 5.23 mmol/L.
- Day 540: Serum Free Immunoglobulin Light Chain, Kappa 4.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.8 mg/dL; Hemoglobin 5.95 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 342 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 31 g/L; Total Protein 5.7 g/dL; Glucose 4.62 mmol/L.
- Day 624: Serum Free Immunoglobulin Light Chain, Kappa 4.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.83 mg/dL; Hemoglobin 6.51 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 371 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.08 mmol/L; Albumin 34 g/L; Total Protein 6.1 g/dL; Glucose 5.39 mmol/L.
- Day 734: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.77 mg/dL; Beta 2 Microglobulin 0.3 µg/mL; Hemoglobin 6.26 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 152 ×10⁹/L; Creatinine 414 µmol/L; Blood Urea Nitrogen 13.2 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 5.45 mmol/L.
- Day 873: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.32 mg/dL; Immunoglobulin G 7.38 g/L; Immunoglobulin A 0.73 g/L; Immunoglobulin M 0.23 g/L; Hemoglobin 6.51 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 348 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.08 mmol/L; Albumin 35 g/L; Total Protein 6.3 g/dL; Glucose 5.5 mmol/L.
- Day 1,030: Serum Free Immunoglobulin Light Chain, Kappa 5.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3 mg/dL; Immunoglobulin G 7.77 g/L; Immunoglobulin A 0.72 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 5.95 mmol/L; Leukocytes 3.22 ×10⁹/L; Absolute Neutrophil 1.57 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 384 µmol/L; Blood Urea Nitrogen 12.9 mmol/L; Calcium 2.15 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 6.05 mmol/L.
- Day 1,093: M Protein 0 g/dL; Immunoglobulin G 9.42 g/L; Immunoglobulin A 0.86 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 6.14 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 1.88 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 342 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 5.72 mmol/L.
- Day 1,156: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.36 mg/dL; Immunoglobulin G 111 g/L; Immunoglobulin A 1.14 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 4.92 ×10⁹/L; Absolute Neutrophil 2.28 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 350 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 7.4 g/dL; Glucose 5.34 mmol/L.

Other clinical attributes
- Day 1: Weight: 78 kg; Height: 172 cm.

Biospecimens (3 samples)
- Sample MMRF_1645_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1645_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
- Sample MMRF_1645_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 175 days.
